TCGA case TCGA-55-8513 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Bronchus and lung; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a3fd20b2-e001-44ab-9716-754e5ae70808

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 77 years; Vital status: Alive.

Diagnoses (2)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C34.30; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 77.4 years (28,284 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Erlotinib Hydrochloride; Days to treatment start: 352 days; Days to treatment end: 460 days (1.3 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed Disodium; Days to treatment start: 561 days (1.5 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Mucinous adenocarcinoma). Age at diagnosis: 78.3 years (28,601 days); Days to diagnosis: 317 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Days to follow up: 146 days; Disease response: Tumor Free.
- Day 317 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 317 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 791 days (2.2 years); Disease response: With Tumor.
- Karnofsky performance status: 60; ECOG performance status: 2; Timepoint: Other.

Other clinical attributes
- DLCO (% of predicted): 65; FEV1/FVC before bronchodilator (%): 108; FEV1 before bronchodilator (% of reference): 87.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-55-8513-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.9; Shortest dimension: 0.4.
  Slide TCGA-55-8513-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-55-8513-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-55-8513-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-55-8513-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.6; Intermediate dimension: 0.5; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Mucinous (Colloid) Carcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Anatomic organ subdivision: L-Lower; EGFR mutation status: Yes; Eml4 alk translocation status: Yes; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response.
- Drug treatment 1: Pharmaceutical therapy drug name: Tarceva; Treatment best response: Clinical Progressive Disease.
- Drug treatment 2: Pharmaceutical therapy drug name: Alimta.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; Treatment outcome at TCGA followup: Stable Disease.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 791 days; disease-specific survival: no event (censored), 791 days; disease-free interval: event (new tumor event after initially disease-free), 317 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 317 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-55-8513-01A-11D-2389-01): tumor purity 0.5, ploidy 2, whole-genome doublings 0.
